Somatic mutation profile of tumor specimen ALCH-B3FW-TTP1-A (aliquot ALCH-B3FW-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B3FW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.0 years (21,185 days).
Specimen ALCH-B3FW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4cf2ff2-f206-4968-b122-2baf1bf432db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3FW-NB1-A (Blood Derived Normal), aliquot ALCH-B3FW-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e824cde5-d674-418c-a011-de0324b5c9f2

The open-access MAF lists 408 somatic variants for this specimen: 279 protein-altering or splice-affecting, 88 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 88, Intron 20, Nonsense Mutation 16, Splice Site 14, Frame Shift Del 9, 5'UTR 7, RNA 7, 5'Flank 4, 3'UTR 3, Translation Start Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1499-2A>G p.X500_splice | Splice Site (SNP) | VAF 59/164 reads (36%) | hotspot (GDC flag); catalogued as CS016049, CS083259, COSV57297794, COSV57328330, COSV57333571; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 80/231 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4195G>A p.E1399K | Missense Mutation (SNP) | VAF 92/1148 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.104); catalogued as rs778606487, COSV56854146; called by muse, mutect2
- ABI3BP | c.1139-1G>A p.X380_splice | Splice Site (SNP) | VAF 133/362 reads (37%) | catalogued as rs745527277; called by mutect2, varscan2
- AC134980.2 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60906808; called by muse, mutect2
- ADGRE1 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 38/504 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs747164531, COSV51673857, COSV99165427; called by muse, mutect2
- ARMC5 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.21); catalogued as rs760150629; called by muse, mutect2
- ARPP21 | c.2135C>A p.P712Q | Missense Mutation (SNP) | VAF 107/343 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99491561; called by muse, mutect2, varscan2
- ATP7B | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 286/643 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as CD045096; called by muse, mutect2, varscan2
- BCS1L | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 48/1162 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.289); catalogued as rs778769841, CM070654; called by muse, mutect2
- BIRC7 | c.85C>A p.R29S | Missense Mutation (SNP) | VAF 99/356 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs775279603, COSV53901161; called by muse, mutect2, varscan2
- C1orf94 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs752960436; called by muse, mutect2, varscan2
- CACNA1S | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 228/701 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62944039; called by muse, mutect2, varscan2
- CDH18 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 72/1230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56909829; called by muse, mutect2
- COLGALT1 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 13/256 reads (5%) | catalogued as COSV53111822; called by muse, mutect2
- COLGALT2 | c.1818G>C p.K606N | Missense Mutation (SNP) | VAF 42/576 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs761369535; called by muse, mutect2
- CPB1 | c.687+2T>A p.X229_splice | Splice Site (SNP) | VAF 226/581 reads (39%) | catalogued as rs1424482489; called by muse, mutect2, varscan2
- CPED1 | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 88/358 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs766516373; called by muse, mutect2, varscan2
- CRAMP1 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 21/341 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366834613; called by muse, mutect2
- CRB1 | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 13/414 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as rs1372774777, CD040886, HM060034; called by muse, mutect2
- CSMD2 | c.6820C>A p.R2274S | Missense Mutation (SNP) | VAF 131/628 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99585161; called by muse, mutect2, varscan2
- CSMD3 | c.4372C>G p.L1458V (on ENST00000297405 / NM_001363185.1; = p.L1354V on NM_052900.3) | Missense Mutation (SNP) | VAF 36/790 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as COSV52226826; called by muse, mutect2
- CUBN | c.3790G>T p.G1264C | Missense Mutation (SNP) | VAF 313/1029 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); catalogued as rs1173928997, COSV64723131; called by muse, mutect2, varscan2
- DNAH7 | c.6358G>T p.D2120Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56751887; called by muse, mutect2, varscan2
- DYRK2 | c.576G>T p.Q192H (on ENST00000344096 / NM_006482.3; = p.Q119H on NM_003583.4) | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs555625707; called by muse, mutect2, varscan2
- EXPH5 | c.4011G>T p.R1337S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV56206636; called by muse, mutect2, varscan2
- FANCI | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 127/772 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV55529504; called by muse, mutect2, varscan2
- FBXO40 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 50/247 reads (20%) | catalogued as COSV57523374, COSV57526547; called by muse, mutect2, varscan2
- FER1L6 | c.5251C>A p.R1751S | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67551617; called by muse, mutect2, varscan2
- FGD2 | c.290C>A p.S97* | Nonsense Mutation (SNP) | VAF 63/181 reads (35%) | catalogued as COSV51465153; called by muse, mutect2, varscan2
- FSCN3 | c.1296G>T p.Q432H | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs766279413; called by muse, mutect2, varscan2
- GRIA2 | c.2588C>T p.S863L | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs1481793675, COSV52407352; called by muse, mutect2
- H3C8 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 21/645 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as rs900322167; called by muse, mutect2
- HECW2 | c.2113G>T p.G705C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as rs1449847465, COSV53667058; called by muse, mutect2, varscan2
- ICE1 | c.6776C>T p.A2259V | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV56824312; called by muse, mutect2
- IFNA8 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 175/557 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as rs182964709; called by muse, mutect2, varscan2
- IGHE | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.84); catalogued as rs370048435; called by muse, mutect2
- INSC | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 54/163 reads (33%) | catalogued as COSV65410192; called by muse, mutect2, varscan2
- ITGAL | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs748938835, COSV63325062; called by muse, mutect2
- ITK | c.579del p.R194Afs*71 | Frame Shift Del (DEL) | VAF 178/609 reads (29%) | catalogued as COSV70060509; called by mutect2, pindel, varscan2
- KCNU1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs561683935, COSV67757944; called by muse, mutect2, varscan2
- LILRB5 | c.619T>G p.S207A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs867864472; called by muse, mutect2
- LRFN3 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV55817159; called by muse, mutect2
- LRRTM1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 49/498 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV54440753, COSV54447550; called by muse, mutect2
- MED15 | c.1510C>T p.P504S (on ENST00000263205 / NM_001003891.3; = p.P464S on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs139254277; called by muse, mutect2, varscan2
- MGAT5B | c.1502G>A p.R501Q (on ENST00000569840 / NM_001199172.2; = p.R499Q on NM_144677.3) | Missense Mutation (SNP) | VAF 144/464 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs367973248; called by muse, mutect2
- MGAT5B | c.1504C>A p.P502T (on ENST00000569840 / NM_001199172.2; = p.P500T on NM_144677.3) | Missense Mutation (SNP) | VAF 142/462 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs776224034; called by muse, mutect2
- MLLT10 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56991681; called by muse, mutect2, varscan2
- MLLT3 | c.1576A>T p.I526F | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV63498825; called by muse, mutect2, varscan2
- MTUS2 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs766266716, COSV70920364; called by muse, mutect2, varscan2
- MUC5B | c.7334C>T p.T2445M | Missense Mutation (SNP) | VAF 67/623 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as rs756364374, COSV101500091; called by muse, mutect2, varscan2
- MYH2 | c.3568C>A p.Q1190K | Missense Mutation (SNP) | VAF 325/848 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs768899738; called by muse, mutect2, varscan2
- NOD2 | c.3055C>G p.R1019G | Missense Mutation (SNP) | VAF 189/684 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs104895491, CM060886, CM082981; called by muse, mutect2, varscan2
- NPY1R | c.680T>C p.I227T | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56713449; called by muse, mutect2, varscan2
- NR1H4 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 83/428 reads (19%) | catalogued as COSV58094484; called by muse, mutect2, varscan2
- NRBP2 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs570469629, COSV100589211; called by muse, mutect2
- NSUN2 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99243034; called by muse, mutect2, varscan2
- OR2T12 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 74/296 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs759048168; called by muse, mutect2, varscan2
- OR51E1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV67809970, COSV67810921; called by muse, mutect2, varscan2
- OR5H15 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 58/367 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs142024597, COSV62949374; called by muse, mutect2, varscan2
- OR5J2 | c.827T>A p.M276K | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1434840267; called by muse, varscan2
- OR6F1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 132/488 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57469652; called by muse, mutect2
- PARVG | c.381C>A p.S127R | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV63562324; called by muse, mutect2, varscan2
- PCDH10 | c.893G>C p.R298P | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV52101045, COSV52105935; called by muse, mutect2
- PCDH15 | c.3842G>T p.G1281V | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761583290; called by muse, mutect2, varscan2
- PCDHB3 | c.1787C>A p.S596* | Nonsense Mutation (SNP) | VAF 174/621 reads (28%) | catalogued as COSV50619820; called by muse, mutect2, varscan2
- PDE6B | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 15/360 reads (4%) | catalogued as COSV99727471; called by muse, mutect2
- PGM2L1 | c.834A>T p.K278N | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV53350155; called by muse, mutect2, varscan2
- POLL | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 168/793 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs963299430; called by muse, mutect2, varscan2
- PSPC1 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 198/736 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1466021917; called by muse, mutect2, varscan2
- PTGIS | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 74/1183 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs150671072; called by muse, mutect2
- PTPRD | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 151/561 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100644871, COSV61983891; called by muse, mutect2, varscan2
- RELN | c.4104G>T p.W1368C | Missense Mutation (SNP) | VAF 194/892 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59000847; called by muse, mutect2, varscan2
- ROS1 | c.5642-1G>A p.X1881_splice | Splice Site (SNP) | VAF 36/184 reads (20%) | catalogued as rs776334708; called by muse, mutect2, varscan2
- RSPH9 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 40/666 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs142194323; called by muse, mutect2
- RSPO3 | c.477C>A p.C159* | Nonsense Mutation (SNP) | VAF 88/516 reads (17%) | catalogued as COSV63153391; called by muse, mutect2, varscan2
- SIN3A | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 74/472 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64582666; called by muse, mutect2, varscan2
- SLC9A4 | c.980+1G>A p.X327_splice | Splice Site (SNP) | VAF 23/179 reads (13%) | catalogued as rs754266683, COSV54829700; called by muse, mutect2, varscan2
- SPANXN3 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 124/228 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65140126; called by muse, varscan2
- ST18 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 134/394 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs750211258, COSV52499950, COSV99389969; called by muse, varscan2
- STIL | c.152+1G>T p.X51_splice | Splice Site (SNP) | VAF 51/366 reads (14%) | catalogued as rs771656424, COSV99680672; called by muse, mutect2, varscan2
- STK4 | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 116/440 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV65671998; called by muse, mutect2, varscan2
- SUGP1 | c.762A>G p.K254= | Splice Region (SNP) | VAF 12/353 reads (3%) | catalogued as rs1240855698; called by muse, mutect2
- SUSD1 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs754624821, COSV62585188; called by muse, mutect2, varscan2
- TASOR2 | c.4244G>A p.R1415Q | Missense Mutation (SNP) | VAF 128/398 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV60165744; called by muse, mutect2, varscan2
- TENT5A | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV60788614; called by muse, mutect2, varscan2
- TKTL2 | c.843G>C p.Q281H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV54920812; called by muse, mutect2, varscan2
- TMEM132D | c.3007C>T p.L1003F | Missense Mutation (SNP) | VAF 22/690 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67159362; called by muse, mutect2
- TMEM179 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.412); catalogued as COSV58795544; called by muse, mutect2, varscan2
- TMPRSS11A | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 52/646 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV58358452; called by muse, mutect2
- TOPAZ1 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV59064752; called by muse, mutect2, varscan2
- TRAT1 | c.438C>A p.S146R | Missense Mutation (SNP) | VAF 46/912 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.698); catalogued as rs140785171, COSV55470032; called by muse, mutect2
- TRDN | c.1720+1G>A p.X574_splice | Splice Site (SNP) | VAF 11/93 reads (12%) | catalogued as COSV62126047; called by muse, mutect2, varscan2
- TTN | c.21040C>T p.P7014S (on ENST00000591111; = p.P6087S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/183 reads (26%) | PolyPhen benign (0.121); catalogued as COSV100631423; called by muse, mutect2, varscan2
- U2AF2 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50035829; called by muse, mutect2
- UBE3D | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 117/668 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV52753905; called by muse, mutect2, varscan2
- VGLL3 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs962129357; called by muse, mutect2
- VPS13C | c.5926C>G p.L1976V (on ENST00000644861 / NM_020821.3; = p.L1933V on NM_017684.5) | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as COSV51428884; called by muse, mutect2, varscan2
- VWF | c.5542G>T p.V1848L | Missense Mutation (SNP) | VAF 181/833 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs376993019, COSV54617546; called by muse, mutect2, varscan2
- WDFY3 | c.4270G>A p.V1424M | Missense Mutation (SNP) | VAF 63/333 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as rs1560740580; called by muse, mutect2, varscan2
- YBX3 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 83/321 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs200496858, COSV99685355; called by muse, mutect2, varscan2
- ZNF800 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 51/169 reads (30%) | catalogued as COSV56175996; called by muse, mutect2, varscan2
- ZNF804B | c.1862T>C p.I621T | Missense Mutation (SNP) | VAF 130/411 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1362977285; called by muse, mutect2, varscan2
- AARS1 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 202/665 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCA12 | c.5579A>G p.N1860S (on ENST00000272895 / NM_173076.3; = p.N1542S on NM_015657.3) | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.305); called by muse, mutect2
- ABCB4 | c.2894A>G p.N965S | Missense Mutation (SNP) | VAF 116/602 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ABHD17A | c.862G>A p.E288K (on ENST00000292577 / NM_001130111.2; = p.E339K on NM_031213.4) | Missense Mutation (SNP) | VAF 89/467 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- AC093246.1 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 71/152 reads (47%) | called by muse, mutect2, varscan2
- ADAM32 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 116/525 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB3 | c.3251C>A p.T1084K | Missense Mutation (SNP) | VAF 91/605 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- ADSS2 | c.394A>T p.R132* | Nonsense Mutation (SNP) | VAF 94/342 reads (27%) | called by muse, varscan2
- ALDOA | c.467G>T p.G156V (on ENST00000642816 / NM_001243177.4; = p.G102V on NM_184041.5) | Missense Mutation (SNP) | VAF 26/417 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ARMC3 | c.1987C>A p.P663T | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ATP2C1 | c.1748_1769del p.R583Lfs*10 | Frame Shift Del (DEL) | VAF 91/1035 reads (9%) | called by mutect2, pindel
- AZIN1 | c.647G>C p.R216P | Missense Mutation (SNP) | VAF 27/407 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- B4GALNT4 | c.864G>T p.L288F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- BCL11B | c.1694A>T p.N565I (on ENST00000357195 / NM_001282237.2; = p.N494I on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BCLAF1 | c.2204C>G p.S735C | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by muse, mutect2
- BDP1 | c.1984A>G p.T662A | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- BUB1B | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- C6orf118 | c.175T>A p.Y59N | Missense Mutation (SNP) | VAF 23/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CACNA2D2 | c.3275G>T p.R1092L (on ENST00000479441 / NM_001174051.3; = p.R1085L on NM_006030.4) | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2
- CALHM6 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 53/410 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CANX | c.245+1G>C p.X82_splice | Splice Site (SNP) | VAF 92/285 reads (32%) | called by muse, varscan2
- CAPZA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 43/407 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- CCNB3 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CEP128 | c.2609G>T p.S870I | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- CFAP47 | c.2406T>G p.I802M | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2
- CHRM3 | c.433del p.A146Pfs*5 | Frame Shift Del (DEL) | VAF 43/318 reads (14%) | called by mutect2, pindel, varscan2
- COL12A1 | c.4264G>A p.V1422I | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL22A1 | c.3974C>A p.P1325Q | Missense Mutation (SNP) | VAF 124/923 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- COL22A1 | c.2660G>T p.R887L | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- COL24A1 | c.938A>C p.Q313P | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRHR2 | c.10del p.A4Hfs*147 | Frame Shift Del (DEL) | VAF 67/270 reads (25%) | called by mutect2, pindel, varscan2
- CSMD3 | c.3165G>T p.W1055C (on ENST00000297405 / NM_001363185.1; = p.W951C on NM_052900.3) | Missense Mutation (SNP) | VAF 150/483 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CUZD1 | c.846G>C p.M282I | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CYLC1 | c.1658G>C p.G553A | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- DENND1C | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DGKB | c.2178G>T p.M726I | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- DHX9 | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.272); called by muse, varscan2
- DNAH3 | c.1920+1G>T p.X640_splice | Splice Site (SNP) | VAF 66/183 reads (36%) | called by muse, mutect2, varscan2
- DNAJC13 | c.656T>A p.L219* | Nonsense Mutation (SNP) | VAF 142/790 reads (18%) | called by muse, mutect2, varscan2
- DOK1 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DPP6 | c.1601A>T p.E534V (on ENST00000377770 / NM_001364500.2; = p.E472V on NM_001936.5) | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- DUSP4 | c.580-2A>C p.X194_splice | Splice Site (SNP) | VAF 58/234 reads (25%) | called by muse, varscan2
- E2F3 | c.1004T>A p.L335Q | Missense Mutation (SNP) | VAF 95/621 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- EGF | c.1678C>G p.L560V | Missense Mutation (SNP) | VAF 29/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF4G1 | c.4769G>T p.R1590L (on ENST00000346169 / NM_198241.3; = p.R1395L on NM_004953.5) | Missense Mutation (SNP) | VAF 97/529 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ELAPOR2 | c.1844G>T p.G615V (on ENST00000450689 / NM_001142749.3; = p.G448V on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 172/910 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EXOC2 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, varscan2
- EYS | c.4304A>C p.D1435A | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2
- FAM160A2 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT2 | c.8892G>A p.W2964* | Nonsense Mutation (SNP) | VAF 8/226 reads (4%) | called by muse, mutect2
- FBXL4 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.847); called by muse, mutect2
- FGGY | c.756T>G p.I252M | Missense Mutation (SNP) | VAF 101/434 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- FSHR | c.1870T>A p.F624I | Missense Mutation (SNP) | VAF 182/783 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GALNT13 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- GRID1 | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HHAT | c.1401G>T p.W467C | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.533); called by muse, mutect2
- HMCN1 | c.14450G>T p.W4817L | Missense Mutation (SNP) | VAF 53/985 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGHA2 | c.469G>C p.A157P | Missense Mutation (SNP) | VAF 144/685 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.20T>G p.I7S | Missense Mutation (SNP) | VAF 103/873 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- IL1RL1 | c.1520A>T p.Q507L | Missense Mutation (SNP) | VAF 90/422 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ING5 | c.27C>G p.H9Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2
- IPCEF1 | c.283A>T p.T95S | Missense Mutation (SNP) | VAF 140/559 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IQCH | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 85/336 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IQGAP1 | c.3931G>T p.D1311Y | Missense Mutation (SNP) | VAF 73/361 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ITPKC | c.146C>G p.P49R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.201); called by mutect2, varscan2
- KBTBD3 | c.53A>G p.N18S | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- KCNH4 | c.1435C>G p.Q479E | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, varscan2
- KCNH7 | c.2083C>A p.P695T | Missense Mutation (SNP) | VAF 122/597 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- KCNH8 | c.2336A>G p.Q779R | Missense Mutation (SNP) | VAF 24/543 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- KCNN2 | c.491C>T p.S164L (on ENST00000264773; = p.S376L on NM_021614.4) | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- KCTD3 | c.1939A>G p.M647V | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIR2DL1 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 268/840 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LAMA2 | c.4855C>G p.L1619V | Missense Mutation (SNP) | VAF 167/621 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LCP1 | c.901C>A p.H301N | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, varscan2
- LDB2 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 115/391 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LHX9 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 125/453 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LMLN | c.506A>G p.H169R | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC24 | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- LRRIQ1 | c.4120A>T p.I1374F | Missense Mutation (SNP) | VAF 91/615 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- MACF1 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 114/1022 reads (11%) | called by mutect2, varscan2
- MAGEB3 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MALRD1 | c.2462A>G p.E821G | Missense Mutation (SNP) | VAF 18/696 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.147); called by muse, mutect2
- MAOB | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- MAP4K4 | c.446T>A p.V149E | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MBD5 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 50/978 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- MDN1 | c.12854A>T p.Q4285L | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- MEGF6 | c.3197G>A p.G1066D | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MINAR1 | c.883del p.H295Tfs*19 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by pindel, varscan2
- MINDY3 | c.876T>G p.F292L | Missense Mutation (SNP) | VAF 89/486 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MME | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 197/957 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOCS3 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- MRGBP | c.445A>T p.S149C | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- MROH2B | c.3636G>C p.L1212F | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- MUC5B | c.5171C>A p.T1724N | Missense Mutation (SNP) | VAF 113/408 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- MYO15A | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- NCR3LG1 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- NID1 | c.3472A>T p.S1158C | Missense Mutation (SNP) | VAF 124/445 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NOP10 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 45/794 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- NOTCH3 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 66/642 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPBWR2 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NPC1 | c.3254A>G p.Y1085C | Missense Mutation (SNP) | VAF 57/446 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPC1L1 | c.1196A>T p.Q399L | Missense Mutation (SNP) | VAF 365/1141 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NPHS2 | c.1084C>G p.P362A | Missense Mutation (SNP) | VAF 178/551 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OGDH | c.2674G>T p.A892S | Missense Mutation (SNP) | VAF 100/443 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G9 | c.359A>T p.D120V | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2J2 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR2L13 | c.750C>G p.Y250* | Nonsense Mutation (SNP) | VAF 137/489 reads (28%) | called by muse, mutect2, varscan2
- OR4K13 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 132/588 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR51G2 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR5A2 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 117/283 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- OR5B21 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 94/459 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- OR6T1 | c.835T>A p.C279S | Missense Mutation (SNP) | VAF 85/692 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OTOA | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 32/546 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- OTUD6A | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 240/428 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH11Y | c.3974C>A p.A1325D | Missense Mutation (SNP) | VAF 142/526 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PCDHB16 | c.1731_1732insG p.R578Afs*152 | Frame Shift Ins (INS) | VAF 198/469 reads (42%) | called by mutect2, pindel, varscan2
- PCDHB5 | c.321del p.Q107Hfs*4 | Frame Shift Del (DEL) | VAF 83/384 reads (22%) | called by pindel, varscan2
- PCDHGB6 | c.1341C>A p.D447E | Missense Mutation (SNP) | VAF 36/401 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDE1A | c.808T>A p.F270I | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PHF20 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 75/397 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PKD1L3 | c.2162A>T p.K721M | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PKP3 | c.2297C>A p.A766E | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PMAIP1 | c.108del p.N37Tfs*7 | Frame Shift Del (DEL) | VAF 90/383 reads (23%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.1187G>C p.R396T | Missense Mutation (SNP) | VAF 36/616 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- PRDM14 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PTPRO | c.2079G>T p.L693F | Missense Mutation (SNP) | VAF 164/745 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- RARRES1 | c.411del p.R138Dfs*6 | Frame Shift Del (DEL) | VAF 163/897 reads (18%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.531G>T p.R177S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- RBM47 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- RELN | c.4103G>T p.W1368L | Missense Mutation (SNP) | VAF 195/903 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- RGS9 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 208/539 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ROR1 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 22/597 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2
- RP1L1 | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RPTOR | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 152/435 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RTTN | c.4496T>C p.L1499P | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RUVBL2 | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SAMD9L | c.4402A>T p.R1468W | Missense Mutation (SNP) | VAF 73/378 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SAMM50 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- SCAI | c.942G>T p.Q314H (on ENST00000336505 / NM_001144877.3; = p.Q337H on NM_173690.5) | Missense Mutation (SNP) | VAF 120/287 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SEMA3E | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 29/1046 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.728); called by muse, mutect2
- SERPING1 | c.1344A>T p.E448D | Missense Mutation (SNP) | VAF 34/996 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.422); called by muse, mutect2
- SI | c.1806A>T p.L602F | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A7 | c.2746G>T p.A916S | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SLCO3A1 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 44/185 reads (24%) | called by muse, mutect2
- SLIT3 | c.3556-1G>T p.X1186_splice | Splice Site (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- SP1 | c.2160T>A p.S720R (on ENST00000327443 / NM_138473.3; = p.S713R on NM_003109.1) | Missense Mutation (SNP) | VAF 150/686 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPATA21 | c.1216C>A p.L406M | Missense Mutation (SNP) | VAF 123/294 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- SRP14 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 31/347 reads (9%) | called by muse, mutect2
- ST8SIA5 | c.224+1G>T p.X75_splice | Splice Site (SNP) | VAF 26/336 reads (8%) | called by muse, mutect2
- STAM | c.1210-2A>T p.X404_splice | Splice Site (SNP) | VAF 22/142 reads (15%) | called by muse, varscan2
- STK33 | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUPT20HL1 | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 168/294 reads (57%) | called by muse, mutect2, varscan2
- SYTL2 | c.1959G>C p.K653N (on ENST00000528231 / NM_001162951.2; = p.K629N on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TBC1D12 | c.1214A>G p.N405S | Missense Mutation (SNP) | VAF 17/436 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.336); called by muse, mutect2
- TBCEL | c.1099_1101del p.E367del | In Frame Del (DEL) | VAF 61/453 reads (13%) | called by mutect2, pindel, varscan2
- TENM3 | c.3445A>G p.I1149V | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); called by mutect2, varscan2
- TENM3 | c.7453T>G p.S2485A | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by mutect2, varscan2
- TMEM163 | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 98/439 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM218 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM229A | c.891C>A p.H297Q | Missense Mutation (SNP) | VAF 207/703 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- TMEM54 | c.115del p.H39Mfs*68 | Frame Shift Del (DEL) | VAF 94/470 reads (20%) | called by mutect2, pindel, varscan2
- TNC | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 116/933 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- TRMT10C | c.260A>T p.D87V | Missense Mutation (SNP) | VAF 30/662 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2
- TTLL7 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 87/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.36725A>G p.Q12242R (on ENST00000591111; = p.Q4818R on NM_003319.4) | Missense Mutation (SNP) | VAF 155/684 reads (23%) | PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TTN | c.36724C>A p.Q12242K (on ENST00000591111; = p.Q4818K on NM_003319.4) | Missense Mutation (SNP) | VAF 153/680 reads (23%) | PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UBC | c.291C>G p.D97E | Missense Mutation (SNP) | VAF 196/843 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- USH2A | c.8477C>T p.P2826L | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- USP35 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP47 | c.3859G>A p.D1287N (on ENST00000399455 / NM_001372095.1; = p.D1199N on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.035); called by muse, mutect2
- YWHAZ | c.632A>T p.Y211F | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ZNF28 | c.1591G>T p.V531F | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF777 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ZNF792 | c.1370A>T p.K457I | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZZEF1 | c.2419G>C p.D807H | Missense Mutation (SNP) | VAF 33/734 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); called by muse, mutect2
- A2M | c.4215G>A p.V1405= | Silent (SNP) | VAF 70/393 reads (18%) | called by muse, mutect2, varscan2
- AKAP6 | c.672A>G p.A224= | Silent (SNP) | VAF 130/600 reads (22%) | called by muse, mutect2, varscan2
- ALK | c.2781G>T p.G927= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs1264537420; called by muse, mutect2, varscan2
- APBB1IP | c.399C>T p.A133= | Silent (SNP) | VAF 102/382 reads (27%) | catalogued as rs149374062; called by muse, mutect2, varscan2
- ASH1L | c.3717A>G p.T1239= | Silent (SNP) | VAF 65/392 reads (17%) | catalogued as rs745845037; called by muse, mutect2, varscan2
- ATF6B | c.297C>T p.S99= | Silent (SNP) | VAF 37/237 reads (16%) | catalogued as rs1222115052; called by muse, mutect2, varscan2
- ATXN1L | c.396C>G p.L132= | Silent (SNP) | VAF 18/448 reads (4%) | called by muse, mutect2
- BCLAF1 | c.1404G>T p.V468= | Silent (SNP) | VAF 65/264 reads (25%) | catalogued as COSV62140925; called by muse, mutect2, varscan2
- BICC1 | c.1668C>A p.I556= | Silent (SNP) | VAF 24/337 reads (7%) | called by muse, mutect2
- C16orf96 | c.3099G>A p.Q1033= | Silent (SNP) | VAF 18/328 reads (5%) | called by muse, mutect2
- C8B | c.1380A>C p.P460= | Silent (SNP) | VAF 155/612 reads (25%) | called by muse, mutect2, varscan2
- CALN1 | c.645G>C p.R215= (on ENST00000329008 / NM_001017440.3; = p.R257= on NM_031468.4) | Silent (SNP) | VAF 88/274 reads (32%) | catalogued as COSV61123899; called by muse, mutect2, varscan2
- CCDC186 | c.2322G>T p.R774= | Silent (SNP) | VAF 74/435 reads (17%) | called by muse, mutect2, varscan2
- CDH18 | c.375G>A p.V125= | Silent (SNP) | VAF 70/1224 reads (6%) | catalogued as COSV99939163; called by muse, mutect2
- CEACAM4 | c.663C>T p.I221= | Silent (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- CENPF | c.5334G>A p.E1778= | Silent (SNP) | VAF 11/285 reads (4%) | called by muse, mutect2
- CLEC4E | c.120C>A p.T40= | Silent (SNP) | VAF 57/264 reads (22%) | called by muse, mutect2, varscan2
- COL6A5 | c.6252G>C p.V2084= (on ENST00000312481; = p.V2080= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/270 reads (40%) | called by muse, mutect2, varscan2
- COL7A1 | c.4842G>A p.E1614= | Silent (SNP) | VAF 9/204 reads (4%) | called by muse, mutect2
- COL8A1 | c.709C>A p.R237= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as rs755896312, COSV53732750; called by muse, mutect2, varscan2
- CTLA4 | c.288C>G p.T96= | Silent (SNP) | VAF 112/621 reads (18%) | called by muse, mutect2, varscan2
- CYP2A13 | c.793C>A p.R265= | Silent (SNP) | VAF 125/775 reads (16%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.1752C>A p.S584= | Silent (SNP) | VAF 57/223 reads (26%) | called by muse, mutect2, varscan2
- EMX1 | c.67C>A p.R23= | Silent (SNP) | VAF 72/408 reads (18%) | called by muse, varscan2
- ERCC8 | c.948C>T p.F316= (on ENST00000265038; = p.F297= on NM_000082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/329 reads (5%) | catalogued as rs1275705699, COSV54015619; called by muse, mutect2
- ERF | c.804G>A p.L268= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs754873708; called by muse, mutect2, varscan2
- ERLIN2 | c.231G>T p.G77= | Silent (SNP) | VAF 92/956 reads (10%) | called by muse, mutect2
- EVC | c.2127G>T p.R709= | Silent (SNP) | VAF 75/275 reads (27%) | called by muse, mutect2, varscan2
- GLRA4 | c.295C>A p.R99= | Silent (SNP) | VAF 147/245 reads (60%) | catalogued as COSV101009684, COSV65456206; called by muse, mutect2, varscan2
- GRIN2A | c.603G>A p.Q201= | Silent (SNP) | VAF 144/480 reads (30%) | called by muse, mutect2, varscan2
- GRIN2B | c.1557A>T p.R519= | Silent (SNP) | VAF 155/753 reads (21%) | called by muse, mutect2, varscan2
- GRM7 | c.414C>T p.N138= | Silent (SNP) | VAF 93/271 reads (34%) | catalogued as rs909354514, COSV63128922; called by muse, mutect2, varscan2
- IGSF3 | c.657G>A p.V219= | Silent (SNP) | VAF 49/449 reads (11%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2826A>T p.G942= | Silent (SNP) | VAF 22/625 reads (4%) | called by muse, mutect2
- IRX2 | c.969C>G p.P323= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as COSV57410141; called by muse, mutect2
- IZUMO3 | c.132C>A p.V44= | Silent (SNP) | VAF 196/807 reads (24%) | catalogued as rs1026468520; called by muse, mutect2, varscan2
- JAKMIP2 | c.1443A>G p.L481= | Silent (SNP) | VAF 71/333 reads (21%) | called by muse, mutect2, varscan2
- KALRN | c.5577G>A p.L1859= (on ENST00000360013 / NM_001024660.4; = p.L162= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 119/586 reads (20%) | called by muse, mutect2, varscan2
- KIF2B | c.1557C>A p.T519= | Silent (SNP) | VAF 109/291 reads (37%) | called by muse, mutect2, varscan2
- KIZ | c.1701G>A p.L567= | Silent (SNP) | VAF 66/307 reads (21%) | catalogued as rs773016404; called by muse, mutect2, varscan2
- KRT5 | c.204G>T p.L68= | Silent (SNP) | VAF 61/577 reads (11%) | called by muse, mutect2, varscan2
- LAMB1 | c.555C>T p.V185= | Silent (SNP) | VAF 34/399 reads (9%) | catalogued as rs370325523; called by muse, mutect2
- LBX1 | c.57G>T p.P19= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as COSV100929975; called by muse, mutect2, varscan2
- LILRB3 | c.876C>T p.G292= | Silent (SNP) | VAF 40/92 reads (43%) | called by mutect2, varscan2
- LRP1B | c.12618C>A p.T4206= | Silent (SNP) | VAF 79/327 reads (24%) | called by muse, mutect2, varscan2
- LRRTM4 | c.327T>A p.R109= | Silent (SNP) | VAF 63/267 reads (24%) | called by muse, mutect2, varscan2
- MARCHF11 | c.882C>T p.C294= | Silent (SNP) | VAF 67/134 reads (50%) | called by muse, mutect2
- MLLT10 | c.489A>T p.R163= | Silent (SNP) | VAF 37/253 reads (15%) | called by muse, mutect2, varscan2
- MPRIP | c.2595G>C p.L865= | Silent (SNP) | VAF 22/782 reads (3%) | called by muse, mutect2
- MUC3A | c.375C>A p.T125= | Silent (SNP) | VAF 120/593 reads (20%) | called by muse, mutect2, varscan2
- NHS | c.1599C>G p.A533= | Silent (SNP) | VAF 82/163 reads (50%) | called by muse, mutect2, varscan2
- OBSCN | c.7800C>T p.D2600= | Silent (SNP) | VAF 91/555 reads (16%) | called by muse, mutect2, varscan2
- OR51V1 | c.255G>T p.L85= | Silent (SNP) | VAF 36/264 reads (14%) | catalogued as COSV100343304, COSV100343511; called by muse, mutect2, varscan2
- OR8U1 | c.690A>T p.S230= | Silent (SNP) | VAF 39/270 reads (14%) | called by muse, mutect2, varscan2
- OR9I1 | c.30C>T p.T10= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs771379003, COSV56925288; called by muse, mutect2
- PCDH11Y | c.3975C>T p.A1325= | Silent (SNP) | VAF 143/529 reads (27%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.651C>T p.A217= | Silent (SNP) | VAF 18/307 reads (6%) | catalogued as COSV99549541; called by muse, mutect2
- PLCB1 | c.1932G>T p.G644= | Silent (SNP) | VAF 30/574 reads (5%) | catalogued as rs745933305, COSV62070516; called by muse, mutect2
- PODN | c.1161G>C p.L387= (on ENST00000395871; = p.L339= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 150/468 reads (32%) | called by muse, mutect2, varscan2
- PYHIN1 | c.180C>G p.A60= | Silent (SNP) | VAF 44/164 reads (27%) | called by muse, mutect2, varscan2
- RPL10 | c.114G>T p.R38= | Silent (SNP) | VAF 70/714 reads (10%) | called by muse, mutect2
- RXRG | c.213A>T p.R71= | Silent (SNP) | VAF 57/206 reads (28%) | called by muse, mutect2, varscan2
- SAFB2 | c.1437C>T p.S479= | Silent (SNP) | VAF 125/304 reads (41%) | catalogued as rs761393538; called by muse, mutect2, varscan2
- SGCE | c.207G>C p.G69= | Silent (SNP) | VAF 62/313 reads (20%) | called by muse, varscan2
- SLC12A6 | c.642A>T p.T214= (on ENST00000354181 / NM_001365088.1; = p.T163= on NM_005135.2) | Silent (SNP) | VAF 30/718 reads (4%) | called by muse, mutect2
- SLC23A3 | c.1014T>C p.C338= | Silent (SNP) | VAF 27/315 reads (9%) | called by muse, mutect2
- SLC30A10 | c.273G>C p.A91= | Silent (SNP) | VAF 67/389 reads (17%) | catalogued as rs768453360; called by muse, mutect2, varscan2
- SLC44A5 | c.660T>A p.G220= | Silent (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- STARD8 | c.2484G>C p.L828= | Silent (SNP) | VAF 43/352 reads (12%) | called by muse, mutect2, varscan2
- STRC | c.5070C>G p.V1690= | Silent (SNP) | VAF 34/742 reads (5%) | called by muse, mutect2
- SYNE1 | c.150G>A p.V50= | Silent (SNP) | VAF 26/834 reads (3%) | called by muse, mutect2
- SYNE2 | c.12057C>T p.F4019= | Silent (SNP) | VAF 148/622 reads (24%) | called by muse, varscan2
- TAS2R39 | c.297C>A p.T99= | Silent (SNP) | VAF 134/646 reads (21%) | catalogued as COSV71470939; called by muse, mutect2, varscan2
- TGFB1I1 | c.1284C>T p.H428= (on ENST00000394863 / NM_001042454.3; = p.H411= on NM_015927.4) | Silent (SNP) | VAF 22/416 reads (5%) | catalogued as rs1485818066; called by muse, mutect2
- TGFB2 | c.246G>C p.A82= | Silent (SNP) | VAF 146/538 reads (27%) | called by muse, mutect2, varscan2
- TGIF2LX | c.363C>A p.I121= | Silent (SNP) | VAF 283/599 reads (47%) | catalogued as COSV99383159; called by muse, mutect2, varscan2
- TNIP1 | c.651G>A p.K217= | Silent (SNP) | VAF 109/316 reads (34%) | called by muse, mutect2, varscan2
- TNXB | c.3789G>T p.L1263= (on ENST00000647633; = p.L1016= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- TRERF1 | c.2802C>T p.I934= | Silent (SNP) | VAF 20/428 reads (5%) | catalogued as COSV61669443, COSV61670555; called by muse, mutect2
- TUB | c.177G>A p.R59= (on ENST00000299506 / NM_177972.3; = p.R114= on NM_003320.4) | Silent (SNP) | VAF 78/441 reads (18%) | called by muse, mutect2, varscan2
- TYR | c.249C>G p.V83= | Silent (SNP) | VAF 26/602 reads (4%) | called by muse, mutect2
- UPK3A | c.807G>T p.V269= | Silent (SNP) | VAF 73/295 reads (25%) | catalogued as COSV99343115; called by muse, mutect2, varscan2
- VIRMA | c.1242G>T p.G414= | Silent (SNP) | VAF 172/447 reads (38%) | catalogued as rs529672065; called by muse, mutect2, varscan2
- XIRP2 | c.180A>C p.T60= | Silent (SNP) | VAF 69/342 reads (20%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.93G>T p.T31= | Silent (SNP) | VAF 51/240 reads (21%) | called by muse, mutect2, varscan2
- ZNF208 | c.2265C>A p.G755= | Silent (SNP) | VAF 93/429 reads (22%) | called by muse, mutect2, varscan2
- ZNF521 | c.3672C>T p.N1224= | Silent (SNP) | VAF 24/421 reads (6%) | called by muse, mutect2
- ZNF568 | c.822A>G p.E274= | Silent (SNP) | VAF 498/793 reads (63%) | called by muse, mutect2, varscan2
- ABCA2 | chr9:137033146 C>A | 5'Flank (SNP) | VAF 46/135 reads (34%) | called by muse, mutect2, varscan2
- ADIG | c.*453G>A | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs1011066622; called by muse, mutect2
- AL136982.4 | n.1411G>T | RNA (SNP) | VAF 201/976 reads (21%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83273C>T | Intron (SNP) | VAF 70/1244 reads (6%) | called by muse, mutect2
- ART3 | c.847+53G>T | Intron (SNP) | VAF 103/407 reads (25%) | catalogued as COSV100587763; called by muse, mutect2, varscan2
- BTBD7 | c.-188G>C | 5'UTR (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- CELF2 | c.1076-1357A>T | Intron (SNP) | VAF 28/398 reads (7%) | called by muse, mutect2
- CHRNA2 | c.-1C>T | 5'UTR (SNP) | VAF 83/514 reads (16%) | called by muse, mutect2, varscan2
- CLEC2D | c.461+115A>G | Intron (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- CLEC4A | c.299-904C>A | Intron (SNP) | VAF 42/170 reads (25%) | called by muse, mutect2, varscan2
- COL4A5 | c.3791-2790G>T | Intron (SNP) | VAF 82/413 reads (20%) | called by muse, mutect2, varscan2
- COX5B | c.-13A>G | 5'UTR (SNP) | VAF 86/468 reads (18%) | called by muse, mutect2, varscan2
- CSF2RA | c.647-39C>T | Intron (SNP) | VAF 72/513 reads (14%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12224C>G | Intron (SNP) | VAF 82/491 reads (17%) | catalogued as rs570456590; called by muse, mutect2, varscan2
- CYP4B1 | c.368-293C>G | Intron (SNP) | VAF 19/664 reads (3%) | called by muse, mutect2
- DEK | c.-60A>C | 5'UTR (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- DIAPH2 | c.3241+39984A>G | Intron (SNP) | VAF 15/332 reads (5%) | called by muse, mutect2
- FAM74A3 | n.147G>T | RNA (SNP) | VAF 289/874 reads (33%) | called by muse, mutect2, varscan2
- H2BP2 | n.1061+1853C>A | Intron (SNP) | VAF 197/1018 reads (19%) | called by muse, mutect2, varscan2
- ICE1 | c.-29G>C | 5'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2
- LINC02877 | n.405A>G | RNA (SNP) | VAF 69/215 reads (32%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+798G>C | Intron (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- MED23 | c.*848del | 3'UTR (DEL) | VAF 47/366 reads (13%) | called by mutect2, pindel, varscan2
- MELTF | c.712+1690G>T | Intron (SNP) | VAF 112/644 reads (17%) | catalogued as COSV56383781; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.679C>A | RNA (SNP) | VAF 143/644 reads (22%) | called by muse, mutect2, varscan2
- MUC19 | n.5763C>T | RNA (SNP) | VAF 30/414 reads (7%) | called by muse, mutect2
- MUS81 | c.-7C>T | 5'UTR (SNP) | VAF 8/234 reads (3%) | catalogued as rs1393740307; called by muse, mutect2
- NFATC3 | c.3107-5078G>C | Intron (SNP) | VAF 10/274 reads (4%) | catalogued as rs1231793902; called by muse, mutect2
- NOC2LP2 | n.1213C>G | RNA (SNP) | VAF 61/599 reads (10%) | called by muse, mutect2, varscan2
- NXF5 | n.732G>T | RNA (SNP) | VAF 145/507 reads (29%) | called by muse, mutect2, varscan2
- PARPBP | c.388-2190G>T | Intron (SNP) | VAF 176/716 reads (25%) | catalogued as COSV59675293; called by muse, mutect2, varscan2
- PDLIM4 | c.671-124G>T | Intron (SNP) | VAF 93/240 reads (39%) | called by muse, mutect2, varscan2
- PMS1 | c.418+662G>T | Intron (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- POLR1H | chr6:30056969 T>A | 5'Flank (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- RIMS2 | c.1692+225C>G | Intron (SNP) | VAF 112/785 reads (14%) | called by muse, varscan2
- RNA5-8SP2 | chr16:34159317 T>A | 5'Flank (SNP) | VAF 22/79 reads (28%) | called by muse, varscan2
- RNU6-784P | chr4:70705194 G>C | 5'Flank (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
- SIX2 | c.-47C>A | 5'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1227-80C>A | Intron (SNP) | VAF 30/105 reads (29%) | called by muse, mutect2, varscan2
- TPH2 | c.609-10847C>A | Intron (SNP) | VAF 28/306 reads (9%) | called by muse, mutect2
- ZNF626 | c.*100A>G | 3'UTR (SNP) | VAF 80/252 reads (32%) | catalogued as rs1555769109; called by muse, mutect2, varscan2
